Somatic mutation profile of tumor specimen TARGET-10-PAPJIB-03A (aliquot TARGET-10-PAPJIB-03A-01D) from TARGET case TARGET-10-PAPJIB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (903 days).
Specimen TARGET-10-PAPJIB-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84576f9d-3c2c-4b38-8d0b-20226cbe717a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPJIB-14A (Bone Marrow Normal), aliquot TARGET-10-PAPJIB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a807f95-9fb7-4660-8178-7657cb1d2240

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIT1 | c.270G>C p.M90I | Missense Mutation (SNP) | VAF 61/174 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs483352822, CM136419, CM148229, COSV64170809, COSV64170843, COSV64170960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DBT | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 219/439 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139251881; called by mutect2, varscan2
- DRAM1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 171/421 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1260293236, COSV51599021; called by muse, mutect2, varscan2
- GRIA2 | c.2464G>A p.G822R | Missense Mutation (SNP) | VAF 69/449 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52397066; called by muse, mutect2, varscan2
- IL27RA | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs758109268, COSV54598936; called by muse, mutect2, varscan2
- KALRN | c.3373C>T p.R1125W | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771930077, COSV53754014; called by muse, mutect2, varscan2
- LCOR | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as rs1564645666, COSV53717059; called by muse, mutect2
- MCF2 | c.2665T>C p.S889P | Missense Mutation (SNP) | VAF 333/1222 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1449087111, COSV58489240; called by muse, mutect2, varscan2
- PROM2 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58299436; called by muse, mutect2
- PTPN11 | c.1504T>C p.S502P | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; called by mutect2, varscan2
- SNAP91 | c.773G>C p.G258A | Missense Mutation (SNP) | VAF 110/803 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52127633, COSV99536087; called by muse, mutect2, varscan2
- WNK2 | c.5711C>T p.T1904M (on ENST00000297954 / NM_001282394.1; = p.T1867M on NM_006648.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1018661001, COSV52931137; called by muse, mutect2, varscan2
- ACAN | c.4280A>G p.D1427G | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, varscan2
- SCN5A | c.2268C>T p.F756= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs372271677; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC5A11 | c.675G>A p.A225= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as rs756403795, COSV61740895; called by muse, mutect2, varscan2
